Gene-level copy-number profile of tumor specimen HCM-WCMC-1285-C54-01A from HCMI case HCM-WCMC-1285-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 34.0 years (12,423 days).
Specimen HCM-WCMC-1285-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0924df5d-b0b2-4ed6-b641-f03e7a952ecb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1285-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/612d1726-7a01-406f-8689-96e6f7a2fb48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 222; copy number 1: 5,376; copy number 2: 51,586; copy number 3: 1,069; copy number 4: 99; copy number 5: 34; copy number 6: 13; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 222 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,960,927–56,977,606, 2 genes: AC069307.1, NOA1.
- chr6:57,919,784–57,961,501, 4 genes: GUSBP4, AL021368.4, POM121L14P, LINC00680.
- chr7:98,794,718–98,794,824, 1 gene: RNU6-393P.
- chr8:70,051,651–70,078,032, 2 genes: PRDM14, RNU1-101P.
- chr11:70,372,246–70,398,488, 1 gene (within-gene range 0–2): AP000487.1.
- chr13:111,316,184–112,108,015, 9 genes: TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr14:18,333,726–19,830,253, 75 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–1): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr17:46,762,506–47,100,323, 12 genes: WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P.
- chr17:74,424,851–74,451,653, 1 gene: GPRC5C.
- chr21:7,744,962–13,016,692, 70 genes (broad region; genes not listed).
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,219,849–43,226,606, 2 genes, copy number 8: AC010883.3, ZFP36L2.
- chr2:43,230,836–43,596,046, 3 genes, copy number 5 (within-gene range 4–5): THADA, RNU6-958P, RN7SL531P.
- chr6:11,414,636–11,515,710, 2 genes, copy number 6 (within-gene range 3–6): AL445430.2, AL445430.1.
- chr6:26,158,146–26,322,292, 27 genes, copy number 5: H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P.
- chr15:92,819,540–93,027,996, 4 genes, copy number 5 (within-gene range 2–5): CHASERR, AC013394.1, CHD2, MIR3175.
- chr19:58,543,299–58,605,223, 11 genes, copy number 6 (within-gene range 3–6): RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 3,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
